Somatic mutation profile of tumor specimen 0DV2RX from CCDI case PBCLJZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 12.0 years (4,389 days).
Specimen 0DV2RX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51bf5c59-e8a9-411b-bcca-76885eb872d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV2QU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/909619db-26f6-4e82-bfb3-28c0f1a9254c

The open-access MAF lists 141 somatic variants for this specimen: 98 protein-altering or splice-affecting, 19 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 19, Intron 14, 3'UTR 5, 5'UTR 4, Splice Site 4, Nonsense Mutation 2, 5'Flank 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR4 | c.1648G>C p.V550L | Missense Mutation (SNP) | VAF 961/2315 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52800715, COSV52802492, COSV52804538; called by muse, mutect2, varscan2
- SOS1 | c.1316A>C p.Q439P | Missense Mutation (SNP) | VAF 405/1299 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as rs1057517861; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 194/1012 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 155/758 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV52703732; called by muse, mutect2, varscan2
- ANKRD31 | c.4187T>G p.F1396C | Missense Mutation (SNP) | VAF 374/1227 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs771561924; called by muse, mutect2, varscan2
- ARSH | c.1177G>A p.G393R | Missense Mutation (SNP) | VAF 205/640 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs145391454, COSV101139759; called by muse, mutect2, varscan2
- B3GAT1 | c.655G>A p.V219I | Missense Mutation (SNP) | VAF 121/781 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473343688, COSV56999995; called by muse, mutect2, varscan2
- BDKRB1 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 226/1325 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs778928912, COSV99387707; called by muse, mutect2, varscan2
- BIRC5 | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 135/755 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs750736960; called by muse, mutect2, varscan2
- CACNA1C | c.1259A>G p.D420G | Missense Mutation (SNP) | VAF 147/1188 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59729534; called by muse, mutect2, varscan2
- CDC45 | c.*1+1G>A | Splice Site (SNP) | VAF 112/584 reads (19%) | catalogued as rs868478591; called by muse, mutect2, varscan2
- CEP250 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 128/1696 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100698942; called by muse, mutect2
- DCHS1 | c.5734C>T p.R1912C | Missense Mutation (SNP) | VAF 51/263 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.438); catalogued as rs537298642, COSV100202122; called by muse, mutect2, varscan2
- DKK2 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 200/1018 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1224653488, COSV53398183, COSV53400723; called by muse, mutect2, varscan2
- EXD3 | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 71/687 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1002428367, COSV59813331, COSV59814592; called by muse, mutect2, varscan2
- FABP12 | c.224C>T p.T75M | Missense Mutation (SNP) | VAF 84/1280 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs536105592, COSV64617976; called by muse, mutect2
- FAM124B | c.61G>A p.G21S | Missense Mutation (SNP) | VAF 98/978 reads (10%) | SIFT tolerated (0.76); PolyPhen benign (0.284); catalogued as rs374014077; called by muse, mutect2, varscan2
- FOXN4 | c.943C>T p.R315W | Missense Mutation (SNP) | VAF 46/747 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs762307757, COSV100142015; called by muse, mutect2
- GIMAP7 | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 112/1421 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1360697139; called by muse, mutect2
- GRIN3B | c.1412C>A p.A471D | Missense Mutation (SNP) | VAF 36/398 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs753813570; called by muse, mutect2
- HPGD | c.662+1G>A p.X221_splice | Splice Site (SNP) | VAF 86/542 reads (16%) | catalogued as rs377261970; called by muse, mutect2, varscan2
- KIAA1614 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 80/434 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs761148715; called by muse, mutect2, varscan2
- KIF21A | c.3652C>T p.P1218S (on ENST00000361418 / NM_001378440.1; = p.P1205S on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/934 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.024); catalogued as COSV100735536; called by muse, mutect2
- KIF2B | c.150C>G p.N50K | Missense Mutation (SNP) | VAF 211/741 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV99274879, COSV99276442; called by muse, mutect2, varscan2
- KLHL23 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 471/1327 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as COSV55866549; called by muse, mutect2, varscan2
- KLHL28 | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 70/1014 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100753190; called by muse, mutect2
- MACF1 | c.21896G>A p.R7299Q (on ENST00000372915; = p.R5344Q on NM_012090.5) | Missense Mutation (SNP) | VAF 123/639 reads (19%) | catalogued as rs745940735; called by muse, mutect2, varscan2
- MLXIP | c.2693C>T p.P898L | Missense Mutation (SNP) | VAF 74/1038 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754435343; called by muse, mutect2
- NOX3 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 159/959 reads (17%) | catalogued as COSV50159539; called by muse, mutect2, varscan2
- OR2T29 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as rs775976277; called by mutect2, varscan2
- OR4C13 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 166/1090 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as rs531184993; called by muse, mutect2, varscan2
- PAK1 | c.299C>A p.P100Q | Missense Mutation (SNP) | VAF 66/986 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53694600; called by muse, mutect2
- PLEKHG6 | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 60/956 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); catalogued as COSV50610713; called by muse, mutect2
- PPA1 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 111/1214 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64683951; called by muse, mutect2
- PRSS35 | c.1159G>A p.V387I | Missense Mutation (SNP) | VAF 149/727 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375255168; called by muse, mutect2, varscan2
- SEC16A | c.5488G>A p.A1830T | Missense Mutation (SNP) | VAF 140/774 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as rs761024052; called by muse, mutect2, varscan2
- SF3B2 | c.628A>G p.M210V | Missense Mutation (SNP) | VAF 154/959 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.013); catalogued as rs1413326228; called by muse, mutect2, varscan2
- SLC6A15 | c.205C>A p.Q69K | Missense Mutation (SNP) | VAF 241/1564 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV57021761; called by muse, mutect2, varscan2
- STAB1 | c.468C>G p.F156L | Missense Mutation (SNP) | VAF 52/882 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); catalogued as COSV100401320; called by muse, mutect2
- TMEM132D | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 60/520 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs751041490, COSV70594645; called by muse, mutect2, varscan2
- TMEM156 | c.539C>G p.S180W | Missense Mutation (SNP) | VAF 146/915 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.177); catalogued as COSV60744273; called by muse, mutect2
- TMEM215 | c.353G>T p.R118M | Missense Mutation (SNP) | VAF 32/380 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.575); catalogued as COSV100713134; called by muse, mutect2
- TPTE | c.505C>T p.L169F (on ENST00000618007 / NM_199261.4; = p.L151F on NM_199259.4) | Missense Mutation (SNP) | VAF 122/2450 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as rs556698994; called by muse, mutect2
- UBAP2 | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 144/920 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62547323; called by muse, mutect2, varscan2
- USHBP1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 78/657 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs202078592, COSV53104853; called by muse, mutect2, varscan2
- WDR27 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 126/624 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.194); catalogued as COSV61210375; called by muse, mutect2, varscan2
- ZAN | c.5083G>A p.D1695N | Missense Mutation (SNP) | VAF 262/847 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.243); catalogued as rs751021889, COSV61810233; called by muse, mutect2, varscan2
- ZNF835 | c.620C>G p.T207R | Missense Mutation (SNP) | VAF 67/495 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV73379249; called by muse, mutect2, varscan2
- ABCB5 | c.2096C>T p.S699F (on ENST00000404938 / NM_001163941.2; = p.S254F on NM_178559.6) | Missense Mutation (SNP) | VAF 402/1320 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ANKRD30BL | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 142/1187 reads (12%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- ASPH | c.311A>C p.K104T | Missense Mutation (SNP) | VAF 104/1626 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATG2A | c.2662C>T p.L888F | Missense Mutation (SNP) | VAF 106/1309 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2
- ATP4A | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 113/850 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAHCC1 | c.7003G>T p.A2335S | Missense Mutation (SNP) | VAF 67/191 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BTAF1 | c.2693C>G p.A898G | Missense Mutation (SNP) | VAF 120/781 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- C8orf58 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 82/1280 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- CENPVL3 | c.520T>G p.C174G | Missense Mutation (SNP) | VAF 17/566 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CFAP46 | c.4923C>G p.C1641W | Missense Mutation (SNP) | VAF 96/1023 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CNGB3 | c.1178+2T>G p.X393_splice | Splice Site (SNP) | VAF 94/1268 reads (7%) | called by muse, mutect2
- CSGALNACT1 | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 124/880 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DENND4B | c.510T>G p.S170R | Missense Mutation (SNP) | VAF 68/970 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- FAM181A | c.623C>A p.T208N | Missense Mutation (SNP) | VAF 53/817 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2
- GPR179 | c.1691C>A p.A564D (on ENST00000621958; = p.A563D on NM_001004334.4) | Missense Mutation (SNP) | VAF 217/678 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- KCNAB3 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 156/563 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- MCM10 | c.1367A>T p.Q456L (on ENST00000484800 / NM_182751.3; = p.Q455L on NM_018518.5) | Missense Mutation (SNP) | VAF 177/946 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- MCM10 | c.1368A>T p.Q456H (on ENST00000484800 / NM_182751.3; = p.Q455H on NM_018518.5) | Missense Mutation (SNP) | VAF 177/946 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- MGAM | c.980T>C p.M327T | Missense Mutation (SNP) | VAF 181/590 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MST1 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 72/1035 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- MUC5AC | c.11668C>T p.P3890S | Missense Mutation (SNP) | VAF 154/1034 reads (15%) | SIFT tolerated (0.91); called by muse, mutect2, varscan2
- MYH13 | c.4433C>A p.S1478Y | Missense Mutation (SNP) | VAF 196/1040 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NSD2 | c.825G>A p.W275* | Nonsense Mutation (SNP) | VAF 147/707 reads (21%) | called by muse, mutect2, varscan2
- NSD2 | c.826A>T p.I276L | Missense Mutation (SNP) | VAF 148/710 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- OAS3 | c.383C>G p.A128G | Missense Mutation (SNP) | VAF 82/696 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR1I1 | c.332A>G p.D111G | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PACSIN3 | c.949G>T p.G317C | Missense Mutation (SNP) | VAF 50/646 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); called by muse, mutect2
- PCGF3 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 71/725 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2
- PITPNM2 | c.2741A>C p.K914T | Missense Mutation (SNP) | VAF 111/729 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- RBM24 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 149/575 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- RYR1 | c.9346T>G p.S3116A | Missense Mutation (SNP) | VAF 103/465 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SEMA6A | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 111/1481 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SFSWAP | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 89/1313 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.629); called by muse, mutect2
- SGCZ | c.591C>A p.H197Q | Missense Mutation (SNP) | VAF 242/1079 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- SLC2A4RG | c.391+1_391+11del p.X131_splice | Splice Site (DEL) | VAF 91/622 reads (15%) | called by mutect2, varscan2
- SNAP91 | c.1261T>C p.S421P | Missense Mutation (SNP) | VAF 232/1248 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- SOGA1 | c.4289T>C p.I1430T | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SPTBN2 | c.2714C>A p.A905E | Missense Mutation (SNP) | VAF 48/580 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); called by muse, mutect2
- STRADB | c.1170G>C p.K390N | Missense Mutation (SNP) | VAF 413/1331 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SVIL | c.4939A>T p.N1647Y (on ENST00000355867 / NM_021738.3; = p.N1221Y on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 127/678 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- TANC2 | c.212-4A>G | Splice Region (SNP) | VAF 225/843 reads (27%) | called by muse, mutect2, varscan2
- TKTL1 | c.1336A>T p.T446S | Missense Mutation (SNP) | VAF 80/777 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- UBE2Z | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 76/963 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.036); called by muse, mutect2
- UGT2B7 | c.202A>T p.N68Y | Missense Mutation (SNP) | VAF 238/1342 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ZBED3 | c.46C>A p.L16M | Missense Mutation (SNP) | VAF 48/662 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.276); called by muse, mutect2
- ZBTB20 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 137/781 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZNF200 | c.893A>G p.H298R | Missense Mutation (SNP) | VAF 156/784 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ZNF280B | c.1516_1521del p.S506_L507del | In Frame Del (DEL) | VAF 142/807 reads (18%) | called by mutect2, varscan2
- ZNF283 | c.712A>C p.K238Q | Missense Mutation (SNP) | VAF 94/1184 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.917); called by muse, mutect2
- ZNF552 | c.739A>G p.K247E | Missense Mutation (SNP) | VAF 132/870 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ASXL1 | c.2556A>C p.S852= | Silent (SNP) | VAF 491/1658 reads (30%) | called by muse, mutect2, varscan2
- BCL2L13 | c.1431G>A p.G477= | Silent (SNP) | VAF 127/688 reads (18%) | called by muse, mutect2, varscan2
- CHD5 | c.4056C>T p.N1352= | Silent (SNP) | VAF 114/674 reads (17%) | catalogued as rs778348411, COSV52427796; called by muse, mutect2, varscan2
- CNKSR2 | c.2553C>T p.S851= | Silent (SNP) | VAF 172/525 reads (33%) | catalogued as rs756634355; called by muse, varscan2
- DISP3 | c.3981C>T p.G1327= | Silent (SNP) | VAF 99/511 reads (19%) | catalogued as rs768195621, COSV99610389; called by muse, mutect2, varscan2
- DSCAM | c.1437G>C p.G479= | Silent (SNP) | VAF 155/790 reads (20%) | called by muse, mutect2, varscan2
- F5 | c.5769C>A p.I1923= | Silent (SNP) | VAF 149/899 reads (17%) | catalogued as COSV63123887; called by muse, mutect2, varscan2
- GDF5 | c.306C>T p.G102= | Silent (SNP) | VAF 98/772 reads (13%) | catalogued as rs920670845; called by muse, mutect2, varscan2
- NAPA | c.627G>A p.A209= | Silent (SNP) | VAF 110/709 reads (16%) | catalogued as rs778477017, COSV99645880; called by muse, mutect2, varscan2
- NPAS2 | c.924A>G p.K308= | Silent (SNP) | VAF 253/784 reads (32%) | called by muse, mutect2, varscan2
- PKD1L1 | c.1332G>A p.A444= | Silent (SNP) | VAF 172/1748 reads (10%) | catalogued as rs751056603, COSV56975400; called by muse, mutect2
- RAB13 | c.528G>T p.R176= | Silent (SNP) | VAF 269/1075 reads (25%) | called by muse, varscan2
- RSPH10B2 | c.1548C>T p.L516= | Silent (SNP) | VAF 286/1039 reads (28%) | catalogued as COSV51868678, COSV99786208; called by muse, mutect2, varscan2
- TMEM131L | c.897T>C p.D299= | Silent (SNP) | VAF 157/740 reads (21%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.1659G>A p.R553= | Silent (SNP) | VAF 95/1553 reads (6%) | catalogued as COSV101226722; called by muse, mutect2
- USP49 | c.1860C>T p.C620= | Silent (SNP) | VAF 106/978 reads (11%) | called by muse, mutect2, varscan2
- XYLT1 | c.942C>T p.D314= | Silent (SNP) | VAF 58/794 reads (7%) | catalogued as rs758450754, COSV54476714; called by muse, mutect2
- ZIM3 | c.1176A>G p.E392= | Silent (SNP) | VAF 76/833 reads (9%) | called by muse, mutect2
- ZP1 | c.1731C>T p.G577= | Silent (SNP) | VAF 129/949 reads (14%) | catalogued as rs755321844; called by muse, mutect2, varscan2
- AL441992.2 | c.*943G>T | 3'UTR (SNP) | VAF 9/161 reads (6%) | catalogued as rs959874748; called by muse, mutect2
- ANKRD28 | c.1184-98G>A | Intron (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- APOBEC3G | c.581+92C>A | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2
- ARMH1 | c.921-42G>A | Intron (SNP) | VAF 18/178 reads (10%) | catalogued as rs1167375851; called by muse, mutect2
- B3GALT6 | c.*22G>A | 3'UTR (SNP) | VAF 30/366 reads (8%) | catalogued as rs1477482908; called by muse, mutect2
- C7orf57 | c.241+71C>A | Intron (SNP) | VAF 14/176 reads (8%) | called by muse, mutect2
- CD68 | chr17:7579584 del TT | 5'Flank (DEL) | VAF 22/84 reads (26%) | catalogued as rs969782123; called by mutect2, varscan2
- CYP4X1 | c.*77G>T | 3'UTR (SNP) | VAF 91/262 reads (35%) | called by muse, mutect2, varscan2
- DISP2 | c.-51_-43del | 5'UTR (DEL) | VAF 10/64 reads (16%) | catalogued as rs749138299; called by mutect2, varscan2
- DPAGT1 | c.1006-25T>G | Intron (SNP) | VAF 26/334 reads (8%) | called by muse, mutect2
- EPCAM | c.*85T>C | 3'UTR (SNP) | VAF 94/298 reads (32%) | catalogued as rs936577951; called by muse, mutect2, varscan2
- EXOSC9 | c.605+63C>G | Intron (SNP) | VAF 72/518 reads (14%) | catalogued as rs1368839230; called by muse, mutect2, varscan2
- FBXL13 | c.496-5460C>A | Intron (SNP) | VAF 76/920 reads (8%) | called by muse, mutect2
- KRTAP22-2 | c.*25C>A | 3'UTR (SNP) | VAF 92/919 reads (10%) | called by muse, mutect2
- OPLAH | c.2871+26C>T | Intron (SNP) | VAF 132/967 reads (14%) | catalogued as rs782781768; called by muse, mutect2, varscan2
- OR13C3 | c.-30C>A | 5'UTR (SNP) | VAF 52/636 reads (8%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as COSV55814242; called by muse, mutect2
- PIAS3 | c.1621-97G>C | Intron (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.698+52954A>G | Intron (SNP) | VAF 74/588 reads (13%) | catalogued as rs572378309, COSV51655429; called by mutect2, varscan2
- RPA2 | c.10+23G>C | Intron (SNP) | VAF 218/1147 reads (19%) | called by muse, mutect2, varscan2
- SAMD15 | c.-52C>T | 5'UTR (SNP) | VAF 93/486 reads (19%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.342-49C>A | Intron (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- TMEM42 | c.192+85G>A | Intron (SNP) | VAF 5/143 reads (3%) | called by muse, mutect2
- WNT3A | c.-35C>T | 5'UTR (SNP) | VAF 30/168 reads (18%) | catalogued as rs1207816826; called by muse, mutect2, varscan2
